Surgical pathology report (de-identified scan), TCGA case TCGA-78-7535, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7535-01A (Primary Tumor).

[page 1 of 2]
1: LEFT UPPER LOBE

Macroscopy:

Specimen consists of a left upper lobectomy measuring 205 x 135 x approximately 60 mm and weighing 503 g in the fixed state. Situated within the upper part of the lobe there is a large mass present medially. The pleural surface overlying this mass appears intact. On sectioning through the lobe this mass measures approximately 72 mm in maximum dimension. It has a lobulated cream appearance on cut surface and comes to within 1 mm of the pleural surface. Tumour is present surrounding the segmental bronchus but does not appear to have eroded through the bronchial wall. The endobronchial resection margin is clear of tumour. On sectioning through the remainder of the lung parenchyma there is anthracosis but no evidence of emphysema and no further lesions are identified. There is a small focus of cyst or bullous formation present at the apex. [RS taken through hilar lymph nodes, A and B; bronchovascular resection margin, C; tumour with overlying pleura, D-F; tumour surrounding bronchus, G and H; tumour and adjacent lung, I; tumour and apical blebs, J; macroscopically normal lung, K and L].

Microscopy:

Sections show a poorly differentiated adenocarcinoma. The lesion is subpleural and in areas there are features suspicious for pleural invasion. No tumour is present on the pleural surface. Special stains to assess pleural invasion are being performed. There is no blood vessel invasion and no lymphatic permeation is seen. The lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. The adjacent lung shows evidence of emphysema.

2: PULMONARY VEIN NODE

Macroscopy:

Specimen consists of two fragments of dark tan tissue measuring in aggregate 18 x 6 x 4 mm. [BIT, 2A].

Microscopy:

Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

3: INTERLOBAR NODE

Macroscopy:

Specimen consists of a single piece of dark tan tissue measuring 15 x 10 x 6 mm. [Bisected and BIT, 3A].

Microscopy:

Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

4: NUMBER 5 NODE

Macroscopy:

Specimen consists of a single piece of fibrofatty tissue measuring 14 x 6 x 4 mm. [BIT, 4A].

Microscopy:

[page 2 of 2]
[REDACTED]

Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

5: NUMBER 10 NODE

Macroscopy:

Specimen consists of a single piece of dark tan tissue measuring 18 x 10 x 4 mm. [BIT, 5A] [REDACTED]

Microscopy:

Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

Summary:

Lung and lymph nodes:

- 1: Poorly differentiated adenocarcinoma; 72 mm in maximal dimension.
- 2: No vascular invasion present.
- 3: Possible pleural invasion identified; special stains are being performed.
- 4: Clear of bronchial margin.
- 5: T2N0MX

T-28000 M-81403 P1-03000

Reported by [REDACTED]
Anatomical Pathologist
[REDACTED]

[REDACTED]

ADDENDUM REPORT

The carcinoma appears to extend just through the elastic laminae of the pleura. There is no extension onto the pleural surface, though.

[REDACTED]

Source: NCI Genomic Data Commons file 9a88bd76-412a-433e-a027-14ae3afe06fe (TCGA-78-7535.217E5C9A-950F-46C0-A022-5ECE5205D9D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).